Somatic mutation profile of tumor specimen ALCH-B0AQ-TTP1-A (aliquot ALCH-B0AQ-TTP1-A-2-0-D-A680-36) from ALCHEMIST case ALCH-B0AQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.6 years (21,418 days).
Specimen ALCH-B0AQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96a6116d-0b54-4f15-b2d4-99295c3f9b73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AQ-NB1-A (Blood Derived Normal), aliquot ALCH-B0AQ-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c50d398-ceb2-4a3c-9824-7daafbfda29a

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2256del p.L747_S752del | In Frame Del (DEL) | VAF 47/566 reads (8%) | hotspot (GDC flag); catalogued as rs121913440, COSV51767308, COSV51778874; ClinVar: drug response; called by mutect2, pindel
- AGPAT5 | c.1074G>C p.L358= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as rs961175689; called by muse, mutect2
- WDR26 | c.528C>G p.V176= (on ENST00000414423 / NM_001379403.1; = p.V76= on NM_025160.7) | Silent (SNP) | VAF 9/219 reads (4%) | catalogued as COSV54359198; called by muse, mutect2
